Gene-level copy-number profile of tumor specimen TCGA-LN-A4A5-01A from TCGA case TCGA-LN-A4A5, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 49.7 years (18,160 days).
Specimen TCGA-LN-A4A5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.a6952c80-3d9f-4a27-a76e-3ce76ab7f438.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A4A5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/77c4ca5e-f4de-43fb-9072-cceca03617bf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 18,217; copy number 2: 36,675; copy number 3: 1,969; copy number 4: 2,525; copy number 5: 157; copy number 6: 4; copy number 7: 36; copy number 9: 36; copy number 11: 1; copy number 12: 14; copy number 15: 12; copy number 17: 100; copy number 24: 3; copy number 37: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A4A5-01A-21D-A25X-01): tumor purity 0.3, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:72,236,281–72,822,781, 8 genes (within-gene range 0–2): LINC01572, AC009075.2, U6, AC004158.1, AC004943.2, RNU7-90P, KRT18P18, AC004943.3.
- chr16:72,805,998–72,821,992, 2 genes: AC004943.1, RNU7-71P.
- chr18:58,476,191–59,700,946, 33 genes: AC105105.4, ALPK2, AC105105.3, AC105105.1, AC104971.2, SNORA108, RPL9P31, AC104971.3, AC104971.1, MALT1, AC104365.1, MRPL37P1, AC104365.3, AC104365.2, RNU6-219P, LINC01926, U8, ZNF532, RNU2-69P, OACYLP, AC040963.1, SEC11C, GRP, RAX, CPLX4, LMAN1, AC016229.2, CCBE1, AC016229.1, AC090213.1, AC010776.1, AC010776.2, AC010776.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 369 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–4,866,311, 100 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:124,141,888–132,481,095, 114 genes, copy number 7–17 (broad region; genes not listed).
- chr11:69,371,463–72,793,599, 123 genes, copy number 5–37 (within-gene range 1–37) (broad region; genes not listed).
- chr15:22,606,022–23,447,243, 32 genes, copy number 7: GOLGA8IP, RN7SL495P, WHAMMP3, AC138649.2, AC138649.5, AC138649.4, PDCD6IPP1, AC138649.3, AC138649.1, AC011767.1, NIPA1, NIPA2, CYFIP1, TUBGCP5, ELMO2P1, GOLGA6L1, AC116165.1, GOLGA8DP, RN7SL106P, ABCB10P1, AC116165.2, MIR4509-1, AC116165.3, AC242376.1, HERC2P7, AC100756.2, AC100756.1, GOLGA8S, RN7SL536P, AC100756.3, HERC2P6, GOLGA6L2.

Autosomal genes at a single copy (total copy number 1): 16,135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
